FM case AD122 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/59f4605f-a71e-4057-bfb5-d648146b2802

Female, 76.0 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
